Somatic mutation profile of tumor specimen ALCH-ACG0-TTP1-A (aliquot ALCH-ACG0-TTP1-A-1-0-D-A49Q-36) from ALCHEMIST case ALCH-ACG0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.6 years (29,085 days).
Specimen ALCH-ACG0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbb60097-f4d0-422c-a10d-e186cd8dcb8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ACG0-NB1-A (Blood Derived Normal), aliquot ALCH-ACG0-NB1-A-1-0-D-A49Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5d621af-c034-45f8-9e35-7ef0db62e32e

The open-access MAF lists 53 somatic variants for this specimen: 42 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 7, Nonsense Mutation 4, Intron 3, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1M2 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 23/699 reads (3%) | catalogued as COSV51566741; called by muse, mutect2
- AUTS2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs757572714; called by muse, mutect2, varscan2
- CHST5 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs773253742, COSV60340213; called by muse, mutect2, varscan2
- GAP43 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as rs200536173; called by muse, mutect2
- H3C1 | c.34A>G p.T12A | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV55121166; called by muse, mutect2
- MRE11 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 22/569 reads (4%) | catalogued as rs1343179190; called by muse, mutect2
- PAPPA | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 36/614 reads (6%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.735); catalogued as rs150638497; called by muse, mutect2
- PEX16 | c.260G>T p.S87I | Missense Mutation (SNP) | VAF 22/625 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV99572252; called by muse, mutect2
- PGK2 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 50/828 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as rs745526510, COSV59165384; called by muse, mutect2
- PTGIS | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 32/614 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV54836960; called by muse, mutect2
- ROS1 | c.3260A>G p.N1087S | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1357481298; called by muse, mutect2
- TRIM32 | c.1676G>T p.G559V | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57792350; called by muse, mutect2
- UGT1A4 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 56/435 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.052); catalogued as rs772532709; called by muse, mutect2, varscan2
- ZNF43 | c.2072C>G p.S691* | Nonsense Mutation (SNP) | VAF 14/332 reads (4%) | catalogued as COSV61683692; called by muse, mutect2
- AL662899.2 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 28/409 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- AQP9 | c.495A>G p.Q165= | Splice Region (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- ARMCX2 | c.1089G>T p.R363S | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2
- BIRC3 | c.794G>T p.W265L | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CA12 | c.1011C>G p.N337K | Missense Mutation (SNP) | VAF 36/744 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); called by muse, mutect2
- CCDC180 | c.1371+4C>A | Splice Region (SNP) | VAF 7/181 reads (4%) | called by muse, mutect2
- CLCA1 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- CNTFR | c.383G>C p.S128T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.899); called by muse, mutect2
- EEF1A2 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.183); called by muse, mutect2
- FUCA1 | c.501A>C p.E167D | Missense Mutation (SNP) | VAF 42/950 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.107); called by muse, mutect2
- GNA13 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); called by muse, mutect2
- HAX1 | c.456A>T p.E152D | Missense Mutation (SNP) | VAF 44/547 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2
- HLA-E | c.444T>A p.N148K | Missense Mutation (SNP) | VAF 24/638 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- IGHV1-2 | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- KCP | c.1999G>T p.G667W (on ENST00000620378; = p.G727W on NM_001366122.1) | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- LAMA5 | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2
- LMOD2 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- LRRC38 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2
- MAP1B | c.4147C>A p.P1383T | Missense Mutation (SNP) | VAF 18/333 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- MMRN1 | c.2367G>T p.L789F | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PPP1R26 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- PRPF6 | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 29/694 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2
- SPTA1 | c.4638T>A p.H1546Q | Missense Mutation (SNP) | VAF 75/1081 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- TAF6L | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.003); called by muse, mutect2
- TBC1D9 | c.20A>T p.E7V | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2
- TNPO3 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); called by muse, mutect2
- TRAV12-2 | c.45G>C p.L15F | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF202 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 46/556 reads (8%) | called by muse, mutect2
- CCDC141 | c.4191A>C p.A1397= | Silent (SNP) | VAF 22/518 reads (4%) | called by muse, mutect2
- DPH2 | c.804G>A p.R268= | Silent (SNP) | VAF 15/362 reads (4%) | called by muse, mutect2
- FLG | c.4077C>A p.S1359= | Silent (SNP) | VAF 112/1332 reads (8%) | catalogued as COSV100912372; called by muse, mutect2
- OBSL1 | c.2865G>A p.L955= | Silent (SNP) | VAF 24/490 reads (5%) | called by muse, mutect2
- PGK2 | c.627G>T p.L209= | Silent (SNP) | VAF 50/840 reads (6%) | catalogued as COSV59163690, COSV59164057; called by muse, mutect2
- PID1 | c.525G>C p.V175= (on ENST00000354069 / NM_001330156.1; = p.V173= on NM_017933.5) | Silent (SNP) | VAF 28/462 reads (6%) | called by muse, mutect2
- TMEM41A | c.330G>T p.V110= | Silent (SNP) | VAF 50/614 reads (8%) | called by muse, mutect2
- ACLY | chr17:41918990 C>T | 5'Flank (SNP) | VAF 12/130 reads (9%) | catalogued as rs1052633349; called by muse, mutect2
- ADCYAP1R1 | c.1046+2948C>T | Intron (SNP) | VAF 35/687 reads (5%) | catalogued as rs1025321164; called by muse, mutect2
- SHROOM3 | c.3753+10A>C | Intron (SNP) | VAF 40/636 reads (6%) | called by muse, mutect2
- ST8SIA5 | c.132-16791G>T | Intron (SNP) | VAF 31/285 reads (11%) | called by muse, mutect2, varscan2
